Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AADQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AADQ-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

Specimen: Liver (7.0 x 5.8 x 3.5 cm, unfixed)

Operation: Partial hepatectomy

Lesion: Multiple, well-defined mass (3.0 x 2.4 cm for the largest one)

Cut surface: Yellowish tan, and granular without necrosis

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 1.2 cm)

Others: Satellite nodule: Yes, multiple

Remaining parenchyma: Cirrhotic

Portal vein invasion: No

Gross photo: Present

Blocks

T1-4, and TB, tumor and surrounding tissue x 5

L and NB, remaining liver parenchyma x 2

RM, resection margin x 1

ICD O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

5/20/14

MICROSCOPIC:

Hepatocellular carcinoma: Yes

Edmondson-Steiner grade

The worst grade III

The major grade II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Cholangiocarcinoma: No

Combined hepatocellular and cholangiocarcinoma: No

Fibrous capsule formation: Complete capsule

Capsular infiltration: No

Septum formation: Yes

Surgical resection margin invasion: No Margin of the clearance (1.2 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Yes

NOT reported. Gross:

Liver, undesignated side, ectomy, Hepatocellular carcinoma

T56000, undesignated side, P10,

DIAGNOSIS:

[page 2 of 2]
Liver, undesignated side, partial hepatectomy: Hepatocellular carcinoma

Suggestion :

Criteria	1/13/14	Yes	No
Dual/Synchronous Primary	Noted		/

Source: NCI Genomic Data Commons file 046da1f9-75a5-42f5-b20a-9594a14ec166 (TCGA-DD-AADQ.EE21BA4A-FA71-4432-9A1F-CFCB991F48C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).